Surgical pathology report (de-identified scan), TCGA case TCGA-NC-A5HP, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CHUV, specimen TCGA-NC-A5HP-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell,
Keratinizing NOS 8071/3
Site @ Lung, upper lobe c34.1
qw 2/1/13

Synoptic translated report

Site : Left lung superior lobe

☐ Central ☒ Peripheral ☐ NA

Number of lesion :

1. Lung squamous cell carcinoma

Tumor size:

1. 4.0 x 3.5 x 3.0 cm

Visceral pleural invasion: ☒ Yes ☐ No ☐ NA

Chest wall invasion : ☐ Yes ☒ No ☐ NA

Histological diagnosis : Poorly differentiated keratinizing squamous cell carcinoma

Node status : N0 (0/34)

TNM : pT2a pN0 (0/34) G3 R0

Pathologist signature:

Date:

Case #	hw 1/24/13	Yes	No
ICD-O Discrepancy			✓
Reviewer initials	RE	Date Review	12/13/12

Source: NCI Genomic Data Commons file 41440af9-4e83-4530-aca8-81042c983bb5 (TCGA-NC-A5HP.7C93B42D-DFF8-4B78-9C02-61296B787C2D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).